Somatic mutation profile of tumor specimen TCGA-12-0618-01A (aliquot TCGA-12-0618-01A-01D-1492-08) from TCGA case TCGA-12-0618, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.5 years (18,071 days).
Specimen TCGA-12-0618-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f93d367-b004-47de-884c-b093cc01b0b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0618-10A (Blood Derived Normal), aliquot TCGA-12-0618-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13977324-1ded-4b06-8b6f-5605742d8d8d

The open-access MAF lists 39 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 26, Silent 6, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 88/98 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ABCB4 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 121/388 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs147998447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AOX1 | c.3182G>A p.R1061H | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs754213226, COSV53495517; called by muse, mutect2, varscan2
- ARHGEF18 | c.2246G>A p.R749Q (on ENST00000359920 / NM_001130955.2; = p.R645Q on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/212 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as rs150543189; called by muse, mutect2, varscan2
- DKK2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 140/299 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs370095806; called by muse, mutect2, varscan2
- EYA1 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV58158058; called by muse, mutect2, varscan2
- FLG2 | c.6047C>T p.T2016I | Missense Mutation (SNP) | VAF 332/739 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.638); catalogued as rs1345557393, COSV66167090; called by muse, mutect2, varscan2
- GATM | c.893A>G p.D298G | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.941); catalogued as COSV67540211; called by muse, mutect2
- IFT172 | c.2626C>A p.H876N | Missense Mutation (SNP) | VAF 248/536 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53130928; called by muse, mutect2, varscan2
- IGFN1 | c.2916T>G p.F972L (on ENST00000295591 / NM_001367841.1; = p.F3429L on NM_001164586.2) | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV55167542; called by muse, mutect2, varscan2
- INCENP | c.1063+1G>A p.X355_splice | Splice Site (SNP) | VAF 49/102 reads (48%) | catalogued as rs1322659119, COSV53913777; called by muse, mutect2, varscan2
- INPP5J | c.2110C>T p.Q704* (on ENST00000331075 / NM_001284285.2; = p.Q336* on NM_001002837.2) | Nonsense Mutation (SNP) | VAF 68/153 reads (44%) | catalogued as COSV100459310, COSV58511865; called by muse, mutect2, varscan2
- KLF17 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761384044, COSV64855973; called by muse, mutect2, varscan2
- LIN9 | c.1639-2A>G p.X547_splice (on ENST00000366808 / NM_001270410.2; = p.X492_splice on NM_173083.3 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 102/205 reads (50%) | catalogued as COSV60244106; called by muse, mutect2, varscan2
- MAG | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as rs202083530, COSV62699294; called by muse, mutect2, varscan2
- NEU2 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 103/229 reads (45%) | catalogued as rs370611873; called by muse, mutect2, varscan2
- NEU4 | c.1365C>G p.F455L (on ENST00000391969 / NM_001167602.3; = p.F467L on NM_080741.4) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57989722; called by muse, mutect2, varscan2
- NUP88 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 236/256 reads (92%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs775555017, COSV56703226, COSV56706453; called by muse, mutect2, varscan2
- OR14J1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 12/375 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs765524812, COSV65845543; called by muse, mutect2
- ORAI2 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV62689275; called by muse, mutect2, varscan2
- ORC3 | c.632A>T p.Q211L | Missense Mutation (SNP) | VAF 94/198 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV57638993; called by muse, mutect2, varscan2
- PHF5A | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV53439599; called by muse, mutect2, varscan2
- PRDM12 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs1452741649, COSV53389923; called by muse, varscan2
- RETNLB | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs370708969, COSV55465147; called by muse, mutect2, varscan2
- SEC62 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.981); catalogued as COSV61260819; called by muse, mutect2, varscan2
- SERPINA11 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 138/311 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.788); catalogued as rs563316230, COSV58241320; called by muse, mutect2, varscan2
- SLITRK6 | c.1407C>A p.N469K | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68389566; called by muse, mutect2, varscan2
- SPTA1 | c.6757C>T p.Q2253* | Nonsense Mutation (SNP) | VAF 217/443 reads (49%) | catalogued as COSV63749900; called by muse, mutect2, varscan2
- TRIM13 | c.997A>T p.T333S | Missense Mutation (SNP) | VAF 248/575 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV53948321; called by muse, mutect2, varscan2
- TSHZ2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141167641, COSV61586883; called by muse, mutect2, varscan2
- ZNF492 | c.183T>A p.N61K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs750501823, COSV71761739; called by muse, mutect2, varscan2
- EZH2 | c.1185_1188del p.E396Kfs*22 (on ENST00000460911 / NM_001203247.2; = p.E401Kfs*22 on NM_004456.5) | Frame Shift Del (DEL) | VAF 145/466 reads (31%) | called by mutect2, pindel, varscan2
- SAMD15 | c.78_79dup p.G27Vfs*52 | Frame Shift Ins (INS) | VAF 63/221 reads (29%) | called by mutect2, pindel, varscan2
- COL6A3 | c.3891C>T p.N1297= | Silent (SNP) | VAF 59/154 reads (38%) | catalogued as rs200722316, COSV55081933; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAGA | c.1119A>C p.S373= | Silent (SNP) | VAF 22/336 reads (7%) | catalogued as COSV67169757; called by muse, mutect2
- RPN2 | c.1839G>A p.T613= | Silent (SNP) | VAF 60/128 reads (47%) | catalogued as rs201803454, COSV52904202; called by muse, mutect2
- TNFSF4 | c.342C>T p.N114= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as COSV56056065; called by muse, mutect2
- TULP2 | c.321C>T p.R107= | Silent (SNP) | VAF 9/248 reads (4%) | catalogued as rs1448894125, COSV55477018; called by muse, mutect2
- ZCCHC2 | c.3519G>A p.T1173= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs376639243; called by muse, mutect2, varscan2
